Surgical pathology report (de-identified scan), TCGA case TCGA-F2-A44H, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site UNC, specimen TCGA-F2-A44H-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Pancreas, bile duct margin, biopsy
- No tumor seen

B: Pancreas pancreatic duct margin, biopsy
- No tumor seen

C: Superior pancreatic lymph node, biopsy
- One lymph node with no malignancy identified (0/1)

D: Aortocaval lymph node, biopsy
- One lymph node with no malignancy identified (0/1)

E: Pancreas, duodenum, pancreaticoduodenectomy

Tumor Histologic Type: adenocarcinoma

Histologic grade: moderately differentiated

Tumor size: 3.5 cm

Extent of invasion:

Peripancreatic soft tissues: present

Duodenum: identified

Ampulla: identified

Lymphatic Invasion: not identified

Venous Invasion: not identified

Perineural Invasion: present

Margins:

Pancreatic neck: negative

Bile duct: negative

Posterior pancreatic surface (deep radial margin): negative (<1 mm)

Peripancreatic soft tissues: negative (<1 mm)

Proximal (gastric): negative

Distal (duodenal): negative

Regional lymph nodes:

Total number with metastasis: 0

ICD-O3

adenocarcinoma, NOS
8140/3

Site: pancreas, head
C25.0

8/23/12 ep

Reviewed: 8/23/12	Date Reviewed	

Signature: [Signature] Date: 8/23/12

[page 2 of 4]
Total number examined: 8 (including specimens A and B)

AJCC PATHOLOGIC TNM STAGE: pT3 pN0 pMx

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Intraoperative Consult Diagnosis:

An intraoperative consultation is requested by

FSA1: Pancreas, bile duct margin, biopsy
- No tumor seen

FSB1: Pancreas, pancreatic duct margin, biopsy
- No tumor seen

Frozen Section Pathologist: ,

Clinical History:

The patient is a -year-old with pancreatic head cancer.

Gross Description:

Specimen A is received fresh in the frozen section room appropriately labeled "bile duct margin for frozen section" and consists of a 2.2 x 0.6 x 0.6 cm red/tan soft tissue fragment with no lumen. The specimen is entirely submitted for frozen section and resubmitted in block FSA1,

Specimen B is received fresh in the frozen section room appropriately labeled "pancreatic duct margin for frozen section" and consists of a 1.0 x 0.8 x 0.3 cm red/tan soft tissue fragment. The specimen is entirely submitted for frozen section and resubmitted in block FSB1,

Specimen C is labeled as "superior pancreatic lymph node, biopsy". Received is a single pink/tan soft tissue fragment with focal erythematous areas and cautery, 1.2 x 0.8 x 0.5 cm. The specimen is serially sectioned and the entire specimen is submitted in block C1,

Specimen D is labeled as "aortocaval lymph node, biopsy" and consists of a white to pink/tan soft tissue fragment 2.2 x 0.9 x 0.7 cm, with focal erythematous areas and cautery. The specimen

[page 3 of 4]
is serially sectioned and submitted in block D1,

Specimen E is labeled "Whipple specimen."

Specimen fixation: formalin

Specimen type: Whipple

Organs received (Whipple Specimen): stomach (3.5 cm long x up to 6.5 cm in circumference), head of pancreas (4 x 3 x 1.5 cm), duodenum (15 cm long x up to 6.7 cm in circumference), common bile duct (3.6 cm long x 1.7 cm in circumference proximally)

Orientation: common bile duct=yellow, pancreatic body margin=blue, uncinate=black, peripancreatic soft tissue=green

Tumor location: head

Tumor dimensions: 3.5 x 3.0 x 2.5 cm

Gross appearance of tumor: solid, firm, variegated, tan/white; There is minimal amount of normal pancreas present.

Extent of invasion:

Confined / non-confined to the pancreas: confined

Involvement of the ampulla: absent

Involvement of the duodenum: absent

Involvement of the bile duct: possibly into wall

Involvement of adjacent vessels: n/a

Spleen (if applicable): n/a

Gallbladder (if applicable): n/a

Stomach (if applicable): uninvolved

Surgical margins:

Pancreatic body: negative (0.2 cm)

Uncinate (Retroperitoneal): negative (<0.1 cm)

[page 4 of 4]
Common Bile duct: negative (0.2 cm)

Proximal margin (stomach): negative (3.5 cm)

Distal margin (duodenum): negative (9.3 cm)

Peripancreatic soft tissues: positive

Lymph nodes: multiple lymph node candidates are identified
ranging in size from 0.5 up to 2.0 cm

Other remarkable findings: none

Digital photograph taken: no

Tissue submitted for special investigation: no

Block summary:

E1, E2 - proximal (stomach) margin, en face
E3 - distal (duodenum) margin, en face
E4 - pancreatic body margin, en face
E5 - uncinate margin with closest approach of tumor,
perpendicular
E6 - closest approach to common bile duct margin, perpendicular,
full thickness, bisected
E7 - remaining common bile duct margin, en face
E8-E9 - mass with relationship to common bile duct and duodenum,
one section, bisected
E10 - tumor with pancreatic duct
E11-E12 - tumor with relationship to ampulla
E13 - two lymph node candidates, one inked black and both
bisected
E14-E15 - largest lymph node candidate, serially sectioned
E16 - two lymph node candidates
E17 - one lymph node candidate, bisected

Source: NCI Genomic Data Commons file 02c1c48a-f029-4d20-8ab3-d366da0f1c29 (TCGA-F2-A44H.92960813-66CA-4229-A935-C02F9B3698F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).